Somatic mutation profile of tumor specimen TARGET-20-PARWXU-09A (aliquot TARGET-20-PARWXU-09A-01D) from TARGET case TARGET-20-PARWXU, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.5 years (557 days).
Specimen TARGET-20-PARWXU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f3df3d6-695a-42bf-93f4-f1eb0fceedd1.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARWXU-10A (Blood Derived Normal), aliquot TARGET-20-PARWXU-10A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92e1ead8-1253-4d79-8e7b-00dd44c70535

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 58/290 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 45/287 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TET2 | c.2903C>T p.P968L | Missense Mutation (SNP) | VAF 73/382 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV54433469; called by muse, mutect2, varscan2
- FAT1 | c.12006G>A p.S4002= | Silent (SNP) | VAF 47/223 reads (21%) | catalogued as rs780198819, COSV71676078; called by muse, mutect2, varscan2
